Somatic mutation profile of tumor specimen TCGA-AX-A2HA-01A (aliquot TCGA-AX-A2HA-01A-12D-A18P-09) from TCGA case TCGA-AX-A2HA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 36.0 years (13,142 days).
Specimen TCGA-AX-A2HA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed0f3fde-2eb7-4683-889e-93358e868a7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2HA-11A (Solid Tissue Normal), aliquot TCGA-AX-A2HA-11A-11D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bde362c-602e-489e-bae3-8213d78344fc

The open-access MAF lists 1,845 somatic variants for this specimen: 1,402 protein-altering or splice-affecting, 402 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 966, Silent 402, Frame Shift Del 290, Frame Shift Ins 57, Nonsense Mutation 51, Intron 20, Splice Site 17, Splice Region 11, In Frame Del 9, RNA 5, 3'UTR 5, 3'Flank 5.

Variants (750 of 1,845; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs128624219, CM940030, COSV54386939; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 60/153 reads (39%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- COL11A2 | c.966dup p.T323Hfs*19 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | catalogued as rs748440351; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNAH5 | c.13338del p.A4447Lfs*16 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs1554017211; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV57246601, COSV57252959; called by muse, mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- GNPTAB | c.2693dup p.Y899Vfs*21 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as rs281864999; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- HNRNPH2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs1555988314, COSV54508490; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- INPPL1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53353022, COSV99995692; called by muse, mutect2, varscan2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.687del p.A230Lfs*16 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs63749897; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH2 | c.1661+1G>T p.X554_splice | Splice Site (SNP) | VAF 28/52 reads (54%) | catalogued as rs267607969, CS056764, CS076631, COSV51878706; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 22/49 reads (45%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 13/40 reads (33%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NOBOX | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as rs193303102, CM118409, COSV56196045; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- TBC1D24 | c.1078C>T p.R360C (on ENST00000646147 / NM_001199107.2; = p.R354C on NM_020705.3) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519629, COSV53547747; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A1BG | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV54051221; called by muse, mutect2
- A2ML1 | c.1886A>G p.E629G | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV100228539, COSV100229633; called by muse, mutect2, varscan2
- ABCA2 | c.917G>A p.R306H (on ENST00000614293; = p.R276H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs778226542, COSV99688623; called by muse, varscan2
- ABCA7 | c.1799T>C p.L600P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99566810; called by muse, mutect2, varscan2
- ABCB8 | c.1688C>T p.T563M (on ENST00000297504 / NM_001282291.2; = p.T546M on NM_007188.5) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs373352833; called by muse, mutect2
- ABCC10 | c.3535G>A p.A1179T (on ENST00000372530 / NM_001198934.2; = p.A1151T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs998696648, COSV55091417; called by muse, mutect2, varscan2
- ABCC2 | c.890del p.K297Rfs*14 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs759781877; called by mutect2, varscan2
- ABCC8 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs755181061, COSV56857996; called by muse, mutect2, varscan2
- AC008676.3 | c.635del p.G212Vfs*24 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs748255153; called by mutect2, pindel, varscan2
- AC068580.4 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs770248571, COSV52588043; called by muse, mutect2, varscan2
- AC131160.1 | c.242C>A p.P81H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100226413; called by muse, mutect2, varscan2
- ACADVL | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99138979; called by muse, mutect2, varscan2
- ACCS | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs923602239, COSV99773032; called by muse, mutect2, varscan2
- ACOT8 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99467917; called by muse, mutect2, varscan2
- ACSL6 | c.106C>A p.L36M (on ENST00000379240; = p.L61M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV99734866; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM2 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698036; called by muse, mutect2, varscan2
- ADAMTS10 | c.438C>T p.H146= | Splice Region (SNP) | VAF 20/43 reads (47%) | catalogued as rs141329649; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTSL4 | c.1808C>A p.P603H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs1434807796, COSV99648201; called by muse, mutect2, varscan2
- ADCY7 | c.2908G>A p.A970T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371865539; called by muse, mutect2, varscan2
- ADGRA3 | c.3467C>T p.A1156V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs776038380, COSV51560136; called by muse, mutect2, varscan2
- ADGRB2 | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99927124; called by muse, mutect2, varscan2
- ADGRG1 | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65635889; called by muse, mutect2, varscan2
- ADGRG2 | c.2674C>T p.R892W (on ENST00000379869 / NM_001079858.3; = p.R889W on NM_005756.4) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1207066736, COSV100492826; called by muse, mutect2
- ADGRG2 | c.472C>T p.R158C (on ENST00000379869 / NM_001079858.3; = p.R155C on NM_005756.4) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.696); catalogued as rs1477983685, COSV100492830; called by muse, mutect2, varscan2
- ADGRG4 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99797365; called by muse, mutect2
- ADRA1D | c.1274G>T p.R425L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV101063183; called by muse, mutect2
- ADRM1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.182); catalogued as rs775536014, COSV53376579; called by muse, mutect2, varscan2
- AEBP1 | c.1756C>A p.R586S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV56261098, COSV99788475; called by muse, mutect2, varscan2
- AFF3 | c.1168_1169insA p.R390Qfs*5 | Frame Shift Ins (INS) | VAF 14/49 reads (29%) | catalogued as COSV100420334; called by mutect2, pindel, varscan2
- AGER | c.355+1G>A p.X119_splice | Splice Site (SNP) | VAF 50/94 reads (53%) | catalogued as rs369394304; called by muse, mutect2, varscan2
- AGFG2 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs527425473, COSV99499624; called by muse, mutect2, varscan2
- AGO2 | c.1839+1G>A p.X613_splice | Splice Site (SNP) | VAF 20/44 reads (45%) | catalogued as rs1306853493, COSV55049693; called by muse, mutect2, varscan2
- AGPS | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as COSV99931792; called by muse, mutect2
- AHCTF1 | c.2356C>T p.P786S (on ENST00000366508; = p.P760S on NM_015446.5) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100404590; called by muse, mutect2, varscan2
- AK2 | c.372C>T p.D124= (on ENST00000354858; = p.D166= on NM_001625.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/26 reads (31%) | catalogued as rs747101216, COSV100710099; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 33/65 reads (51%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKNAD1 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV100645944; called by muse, mutect2, varscan2
- AKR1C3 | c.740dup p.H248Afs*27 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | catalogued as rs1554786256; called by mutect2, pindel, varscan2
- AL645922.1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs764034564, COSV100191332; called by muse, mutect2, varscan2
- ALAS1 | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV100050523; called by muse, mutect2, varscan2
- ALDH8A1 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs533886052, COSV55642834; called by muse, mutect2, varscan2
- ALS2 | c.4832G>A p.R1611Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99970182, COSV99970188; called by muse, mutect2, varscan2
- AMACR | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs573730345, COSV100162908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMOTL1 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100133979; called by mutect2, varscan2
- ANK1 | c.2803C>T p.R935* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV99227255; called by muse, mutect2, varscan2
- ANK3 | c.6715C>T p.R2239C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.981); catalogued as rs747533848, COSV55066315; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5150A>T p.N1717I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99784775; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 10/12 reads (83%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD27 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs1306229833, COSV100042633; called by muse, mutect2, varscan2
- ANKRD29 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760793382, COSV99409334; called by muse, mutect2, varscan2
- ANXA13 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV99147277; called by muse, mutect2, varscan2
- ANXA7 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs370055787, COSV100873468; called by muse, mutect2, varscan2
- AOC3 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as rs573304904, COSV53825277; called by muse, mutect2, varscan2
- AP002512.3 | c.393dup p.V132Cfs*22 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs775245123; called by mutect2, pindel, varscan2
- AP2A2 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs373171866; called by muse, mutect2, varscan2
- AP2B1 | c.1568del p.G523Afs*18 | Frame Shift Del (DEL) | VAF 20/81 reads (25%) | catalogued as COSV51997883, COSV52004011; called by mutect2, pindel, varscan2
- AP3M1 | c.1186G>T p.G396W | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99281401; called by muse, varscan2
- AP5B1 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs896192862, COSV100376191; called by muse, mutect2, varscan2
- APC | c.4196G>A p.R1399H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1431515214, COSV57339858, COSV57361062; called by muse, mutect2, varscan2
- APOA5 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1197451972; called by muse, mutect2
- APOBEC3H | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.911); catalogued as rs769176395, COSV100818874; called by mutect2, varscan2
- AQP12B | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs773771969, COSV101315954; called by muse, mutect2, varscan2
- ARFGEF1 | c.3190G>A p.V1064M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99145488; called by muse, mutect2
- ARHGAP32 | c.2966G>T p.G989V (on ENST00000310343 / NM_001378025.1; = p.G640V on NM_014715.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.116); catalogued as COSV100089701; called by muse, mutect2, varscan2
- ARHGEF15 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs756290079, COSV100729974; called by muse, mutect2, varscan2
- ARHGEF7 | c.424G>A p.V142M (on ENST00000375741 / NM_001113511.2; = p.V121M on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.72); catalogued as rs774308780, COSV54546455; called by muse, mutect2, varscan2
- ARID1B | c.2650G>T p.G884* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as rs1554226059, COSV99271071; called by muse, mutect2, varscan2
- ARID3B | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1218699597, COSV100654805; called by muse, mutect2, varscan2
- ARRDC2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs540013259, COSV99717020; called by muse, mutect2, varscan2
- ASCC3 | c.1058del p.K353Rfs*6 | Frame Shift Del (DEL) | VAF 44/101 reads (44%) | catalogued as rs1361297712; called by mutect2, pindel, varscan2
- ASH1L | c.943G>C p.V315L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV64206224; called by muse, mutect2, varscan2
- ASPM | c.6265G>T p.E2089* | Nonsense Mutation (SNP) | VAF 16/118 reads (14%) | catalogued as COSV99661320; called by muse, mutect2, varscan2
- ASPM | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as rs374323328; called by muse, mutect2, varscan2
- ASPSCR1 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs773864878, COSV100145070; called by muse, mutect2, varscan2
- ATAD2B | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs779453172, COSV53198943; called by muse, mutect2, varscan2
- ATIC | c.1445T>C p.V482A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV99378302; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP13A2 | c.1564G>A p.G522S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs140278172; called by muse, mutect2, varscan2
- ATP13A4 | c.1414del p.Q472Rfs*9 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | catalogued as COSV99793944; called by mutect2, pindel, varscan2
- ATP1A1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1258171077, COSV55191704; called by muse, varscan2
- ATP2A1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774147813, COSV63922373; called by muse, mutect2, varscan2
- ATP2B2 | c.464C>G p.A155G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV59499094; called by muse, mutect2, varscan2
- ATP2B3 | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782643695, COSV99686204; called by muse, mutect2, varscan2
- ATP5F1A | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99959221; called by muse, mutect2, varscan2
- ATP9B | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs749331175, COSV100304378; called by muse, mutect2, varscan2
- ATXN7 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV99895551; called by muse, mutect2, varscan2
- AVPR1B | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs782696904, COSV65637922; called by muse, mutect2, varscan2
- AZIN2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs374895105; called by muse, mutect2, varscan2
- AZIN2 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99613908; called by muse, mutect2
- B4GALNT4 | c.1138A>G p.T380A | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100327931; called by muse, mutect2, varscan2
- BAIAP3 | c.3170C>T p.P1057L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.898); catalogued as rs756747374, COSV50105061; called by muse, mutect2, varscan2
- BAZ1A | c.4621A>C p.N1541H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.092); catalogued as COSV100701231; called by muse, mutect2, varscan2
- BBS2 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99802984; called by muse, mutect2, varscan2
- BCDIN3D | c.695A>C p.N232T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100445591; called by muse, mutect2, varscan2
- BGN | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV100525337; called by muse, mutect2, varscan2
- BIRC6 | c.12778C>T p.R4260* | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as COSV70197627; called by muse, mutect2, varscan2
- BNIP1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV99199479; called by muse, mutect2, varscan2
- BOP1 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs781924844; called by muse, mutect2
- BOP1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs926150063; called by muse, mutect2, varscan2
- BRD3 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs780729968, CM161417, COSV100325357, COSV57707593; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 27/42 reads (64%) | catalogued as rs763134487; called by mutect2, varscan2
- BROX | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs939085791, COSV61799535, COSV61799878; called by muse, mutect2, varscan2
- BRPF3 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1280699159, COSV60208580; called by muse, mutect2, varscan2
- BSX | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.34); catalogued as COSV100545380; called by muse, mutect2
- BTAF1 | c.5146A>G p.T1716A | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99795938; called by muse, mutect2, varscan2
- BTBD3 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.227); catalogued as rs149470256; called by muse, mutect2, varscan2
- BTBD7 | c.3088G>A p.V1030I | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs552454801, COSV100598291; called by muse, mutect2, varscan2
- BTN3A2 | c.949del p.I317Sfs*4 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as COSV62687981; called by mutect2, pindel, varscan2
- C15orf39 | c.1790C>A p.A597D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV100641517; called by muse, mutect2, varscan2
- C19orf47 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs376597651; called by muse, mutect2, varscan2
- C1QB | c.98del p.P33Qfs*24 | Frame Shift Del (DEL) | VAF 17/31 reads (55%) | catalogued as rs1242981172; called by mutect2, pindel, varscan2
- C1S | c.1958T>C p.V653A | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100196817; called by muse, mutect2, varscan2
- C1orf87 | c.1192G>T p.G398W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100967294; called by muse, varscan2
- C20orf194 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.267); catalogued as rs369952939; called by muse, mutect2, varscan2
- C3orf56 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs369125533, COSV67756305; called by muse, mutect2, varscan2
- C4BPA | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65536259; called by muse, mutect2, varscan2
- C4BPB | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54691807, COSV99700203; called by muse, mutect2, varscan2
- CA4 | c.69G>A p.W23* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as rs757856650, COSV99958544; called by muse, mutect2, varscan2
- CABIN1 | c.4483del p.Q1495Rfs*26 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as rs1173897126; called by mutect2, pindel, varscan2
- CACNA1D | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV55440184, COSV55456071; called by muse, mutect2, varscan2
- CACNA1H | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100673668; called by muse, mutect2, varscan2
- CACNA2D4 | c.2374G>A p.V792M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs200749936; called by muse, mutect2, varscan2
- CACNB2 | c.503G>A p.C168Y (on ENST00000324631 / NM_201596.3; = p.C113Y on NM_000724.4) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs773215003, COSV56630337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CAMSAP1 | c.4772G>A p.R1591Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100410506; called by muse, mutect2, varscan2
- CAMSAP1 | c.1062C>A p.H354Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100410508, COSV56723195; called by muse, mutect2
- CAMSAP3 | c.3599G>A p.G1200D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV99352244; called by muse, mutect2, varscan2
- CAMTA1 | c.3382G>A p.V1128M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as rs545301543, COSV57891814; called by muse, mutect2, varscan2
- CAND1 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101607363; called by mutect2, varscan2
- CAND2 | c.1148G>A p.R383H (on ENST00000456430 / NM_001162499.2; = p.R290H on NM_012298.3) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1197680108, COSV55989546; called by muse, mutect2, varscan2
- CAPN6 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs758227137, COSV100137150; called by muse, mutect2, varscan2
- CAPZA2 | c.501T>A p.N167K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV100753983, COSV63266106; called by muse, mutect2, varscan2
- CARMIL3 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs759482752, COSV100549470, COSV100549944; called by muse, mutect2, varscan2
- CARS2 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as rs768491774, COSV99960088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 36/84 reads (43%) | catalogued as rs770159446; called by mutect2, varscan2
- CASZ1 | c.1810G>A p.G604R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199556835, COSV100682312; called by muse, mutect2, varscan2
- CC2D1A | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100528769; called by muse, mutect2, varscan2
- CCDC107 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as rs1244155065, COSV100526385; called by muse, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC183 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1350327804, COSV100273836; called by muse, mutect2
- CCDC24 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV62212272; called by muse, mutect2, varscan2
- CCDC60 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs200062829, COSV59546033; called by muse, mutect2, varscan2
- CCDC73 | c.3196dup p.R1066Kfs*17 | Frame Shift Ins (INS) | VAF 21/71 reads (30%) | catalogued as rs781654336; called by mutect2, pindel, varscan2
- CCDC89 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs775520786, COSV57034441; called by muse, mutect2, varscan2
- CCKBR | c.76del p.A26Rfs*38 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs770600950, COSV58101276; called by mutect2, pindel, varscan2
- CCM2 | c.1012C>A p.L338M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99348236; called by muse, mutect2, varscan2
- CCN3 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs942579392, COSV52383321, COSV99423200, COSV99423483; called by muse, mutect2, varscan2
- CCNA1 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs752851752, COSV99715014; called by muse, mutect2, varscan2
- CCNB1IP1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV100738676; called by muse, mutect2, varscan2
- CCND2 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV54225555; called by muse, mutect2, varscan2
- CCNO | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99248227; called by muse, mutect2, varscan2
- CCNY | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1156497520, COSV99591260; called by muse, mutect2
- CCT3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772429212, COSV55287525; called by muse, mutect2, varscan2
- CCT6B | c.795A>T p.K265N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV100031093, COSV58488345; called by muse, mutect2, varscan2
- CD163 | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs772938688, COSV63131535, COSV63134805; called by muse, mutect2, varscan2
- CD1E | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100937093, COSV63771663; called by muse, mutect2, varscan2
- CD247 | c.393+2T>C p.X131_splice (on ENST00000362089 / NM_198053.3; = p.X130_splice on NM_000734.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100758510; called by muse, mutect2, varscan2
- CD37 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.625); catalogued as COSV100115210; called by muse, mutect2, varscan2
- CD5L | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879069186, COSV100941033, COSV63821041; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDC40 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100309615; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH1 | c.2398C>T p.R800C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782162, CD073586, COSV99028593, COSV99932809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH4 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779693148, COSV64663178; called by muse, mutect2, varscan2
- CDH9 | c.895del p.E299Kfs*31 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | catalogued as COSV99144186; called by mutect2, pindel, varscan2
- CDHR5 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758663203, COSV57643917; called by muse, mutect2, varscan2
- CDK10 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs202105291, COSV57045776, COSV99232613; called by muse, mutect2, varscan2
- CDK11B | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753220778, COSV100477929, COSV58336614; called by muse, mutect2, varscan2
- CDK2AP1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1271472566, COSV55542333; called by muse, mutect2
- CEP20 | c.53del p.K18Rfs*4 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs746479678; called by mutect2, pindel, varscan2
- CEP290 | c.6758G>A p.S2253N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as COSV100470165; called by muse, mutect2, varscan2
- CEP350 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs751567537, COSV100658368; called by muse, mutect2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFAP91 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV56344662, COSV99847100; called by muse, mutect2, varscan2
- CGNL1 | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1199394048, COSV99849351; called by muse, mutect2, varscan2
- CHAT | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV100341086; called by muse, mutect2, varscan2
- CHD5 | c.4025G>A p.G1342D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99315447; called by muse, mutect2, varscan2
- CHD5 | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs144145989; called by muse, mutect2, varscan2
- CHI3L1 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as rs572161451, COSV99704195; called by muse, mutect2, varscan2
- CHRD | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs139430266, COSV99200981; called by muse, mutect2
- CHRM5 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as rs193093417, COSV67248269; called by muse, mutect2, varscan2
- CHRNA7 | c.1016G>A p.C339Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1221150238, COSV100181861; called by mutect2, varscan2
- CHRNB2 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773957177, COSV63807807; called by muse, mutect2, varscan2
- CHST11 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV57985987; called by muse, mutect2, varscan2
- CHST13 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV100081430, COSV60041831; called by muse, mutect2, varscan2
- CHTF18 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs749093068, COSV99136042; called by muse, mutect2, varscan2
- CIAO3 | c.629G>A p.S210N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99285246; called by muse, mutect2, varscan2
- CLDN1 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | catalogued as rs777818543, COSV55045476, COSV99790776; called by muse, mutect2, varscan2
- CLDN18 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs764350012, COSV99481065; called by muse, mutect2, varscan2
- CLEC18C | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs747425645, COSV58499675; called by muse, mutect2, varscan2
- CLIC2 | c.257T>A p.I86N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100425784; called by muse, mutect2, varscan2
- CLIP4 | c.1859G>A p.S620N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV60749225; called by muse, mutect2, varscan2
- CLPX | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as rs756151231, COSV55644445; called by muse, mutect2, varscan2
- CLTCL1 | c.3635A>G p.E1212G | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV99596048; called by muse, mutect2, varscan2
- CMIP | c.1355C>T p.T452M (on ENST00000537098 / NM_198390.2; = p.T358M on NM_030629.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as rs369769411; called by muse, mutect2, varscan2
- CNGA2 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs765240604, COSV61703225, COSV61703724; called by muse, mutect2, varscan2
- CNOT1 | c.5494A>T p.M1832L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55315796; called by muse, mutect2, varscan2
- CNOT1 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1329047920, COSV55316140; called by muse, mutect2, varscan2
- CNOT1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57770720; called by muse, mutect2, varscan2
- CNOT3 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs369127356; called by muse, mutect2
- CNST | c.446T>A p.V149D | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV100829939; called by muse, mutect2, varscan2
- CNTNAP1 | c.553T>C p.Y185H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99227177; called by muse, mutect2, varscan2
- CNTRL | c.4136A>G p.E1379G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs112885964, COSV99444201; called by muse, mutect2, varscan2
- COG2 | c.1141A>G p.N381D | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100794822; called by muse, mutect2, varscan2
- COL16A1 | c.3979C>A p.L1327I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99595747; called by muse, mutect2, varscan2
- COL1A2 | c.3557G>A p.C1186Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99801464; called by muse, mutect2, varscan2
- COL6A2 | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs750097119, COSV99384786; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- COLGALT2 | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV100730936; called by muse, mutect2, varscan2
- COPS6 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as rs755086126, COSV57997287; called by muse, mutect2, varscan2
- COQ8B | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866812916, COSV99699700; called by muse, mutect2, varscan2
- CORIN | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99904645; called by muse, mutect2, varscan2
- COX16 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as COSV101112194; called by muse, mutect2, varscan2
- CPN2 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100103070; called by mutect2, varscan2
- CPT1C | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs959517123, COSV99773749; called by muse, mutect2, varscan2
- CPVL | c.794del p.K265Sfs*11 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs1562753933; called by mutect2, pindel, varscan2
- CRACR2B | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs765049710, COSV100352174; called by muse, mutect2, varscan2
- CRAMP1 | c.3749G>A p.R1250H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as rs778839791, COSV99246204; called by muse, mutect2, varscan2
- CROCC | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as rs1267484882, COSV100978454; called by muse, mutect2, varscan2
- CRYBA4 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs764511323, COSV61321912; called by muse, mutect2, varscan2
- CSF2RA | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs769866070, COSV100818009; called by muse, mutect2, varscan2
- CSMD3 | c.8542C>T p.R2848* (on ENST00000297405 / NM_001363185.1; = p.R2679* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV52187779; called by muse, mutect2, varscan2
- CSN1S1 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs531054138, COSV99887010; called by muse, mutect2
- CSNK1G3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as rs770657288, COSV62057158, COSV62057450; called by muse, mutect2, varscan2
- CSPG4 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1011293001, COSV100414272; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 9/97 reads (9%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTDP1 | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99311282; called by muse, mutect2, varscan2
- CTNNAL1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs747944532, COSV57702470, COSV57705583; called by muse, mutect2, varscan2
- CTRC | c.421T>G p.C141G | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101036489; called by muse, mutect2, varscan2
- CTSL | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as rs975167709, COSV100446767; called by muse, mutect2, varscan2
- CUBN | c.6112G>T p.V2038L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV100913725; called by muse, mutect2, varscan2
- CXCR1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV55282703, COSV99826459; called by muse, mutect2, varscan2
- CYGB | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1287701626, COSV99506187; called by muse, mutect2, varscan2
- DAGLB | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1459548780, COSV99766263; called by muse, mutect2, varscan2
- DCAF11 | c.442T>C p.F148L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs1419232831, COSV100386936; called by muse, mutect2
- DCAF4L2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs755701425, COSV60476952, COSV60481637; called by muse, mutect2, varscan2
- DCAF7 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100177788; called by muse, mutect2, varscan2
- DCHS1 | c.6257C>T p.P2086L | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100202710; called by muse, mutect2, varscan2
- DCLRE1A | c.1032dup p.K345* | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs751315517; called by mutect2, varscan2
- DCLRE1B | c.95T>C p.M32T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99871216; called by muse, mutect2, varscan2
- DDAH1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as rs377746010; called by muse, mutect2, varscan2
- DDB1 | c.2782C>T p.R928C | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57105207; called by muse, mutect2, varscan2
- DDX10 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100490063; called by muse, mutect2, varscan2
- DDX20 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763722623, COSV63831138; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX41 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs773515517, COSV57905510, COSV57905858; called by muse, mutect2, varscan2
- DDX47 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV100774677; called by muse, mutect2, varscan2
- DDX54 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1446437409, COSV100014267; called by muse, mutect2, varscan2
- DDX60L | c.5023C>T p.R1675C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs371572312, COSV99488687; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 30/37 reads (81%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND2C | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.489); catalogued as COSV101283985; called by muse, varscan2
- DEPDC1 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100920526; called by muse, varscan2
- DEPDC7 | c.219T>A p.D73E (on ENST00000241051 / NM_001077242.2; = p.D64E on NM_139160.2) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99572961; called by muse, mutect2
- DIAPH3 | c.3055del p.R1019Efs*12 (on ENST00000400324 / NM_001042517.2; = p.R756Efs*12 on NM_030932.3) | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | catalogued as rs753024929; called by mutect2, varscan2
- DIDO1 | c.1425del p.E476Rfs*4 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs762377755; called by mutect2, varscan2
- DISC1 | c.782G>C p.C261S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99698883; called by muse, mutect2, varscan2
- DLGAP3 | c.2033C>T p.T678M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1225207806, COSV52391086; called by muse, mutect2, varscan2
- DLX6 | c.804del p.N269Tfs*24 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as COSV50295202, COSV99142336; called by mutect2, pindel, varscan2
- DMTF1 | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV100487546; called by muse, mutect2
- DNAAF1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs574238677, COSV57577092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.11551C>T p.R3851C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs751763171, COSV99964610; called by muse, mutect2, varscan2
- DNAH11 | c.3123G>A p.W1041* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100181380; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 17/29 reads (59%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as rs1247906703, COSV99318503; called by muse, mutect2, varscan2
- DNAH2 | c.5933G>A p.R1978H | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150754871; called by muse, mutect2, varscan2
- DNAH5 | c.9947del p.P3316Lfs*22 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs1206989225; called by mutect2, pindel, varscan2
- DNAH9 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52355426, COSV52378439; called by muse, mutect2, varscan2
- DNAJC13 | c.1770+2T>C p.X590_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | catalogued as COSV53445709; called by muse, mutect2, varscan2
- DNM1L | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV99846548; called by muse, mutect2, varscan2
- DOCK11 | c.2483T>C p.V828A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99355008; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as rs748134881; called by mutect2, varscan2
- DOP1A | c.7084A>G p.R2362G | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV99383132; called by muse, mutect2, varscan2
- DOP1B | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs201917816; called by muse, mutect2, varscan2
- DPP6 | c.1323G>T p.K441N (on ENST00000377770 / NM_001364500.2; = p.K379N on NM_001936.5) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100128751, COSV59604429; called by muse, mutect2, varscan2
- DSCAML1 | c.5821C>T p.R1941W (on ENST00000321322; = p.R1881W on NM_020693.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs138436571; called by muse, mutect2, varscan2
- DSG2 | c.2402A>G p.Q801R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs777606703, COSV99853647; called by muse, mutect2, varscan2
- DYNC1H1 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1003040427, COSV100794273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1H1 | c.6933G>A p.W2311* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100795546; called by muse, mutect2, varscan2
- DYNC1LI1 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as COSV99818416; called by muse, mutect2, varscan2
- DYRK1B | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs202191647, COSV99695463; called by muse, mutect2, varscan2
- E2F5 | c.320del p.K107Sfs*11 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | catalogued as rs761281897; called by mutect2, pindel, varscan2
- E2F7 | c.177del p.K59Nfs*29 | Frame Shift Del (DEL) | VAF 38/78 reads (49%) | catalogued as rs771114476; called by mutect2, varscan2
- EBF2 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs202183525, COSV101282305; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs749657822, COSV66964693; called by muse, mutect2, varscan2
- EEF1D | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs562488930, COSV52784809; called by muse, mutect2, varscan2
- EEF2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100501056; called by muse, mutect2, varscan2
- EFCAB5 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100300942; called by muse, mutect2, varscan2
- EFCC1 | c.1593C>T p.N531= | Splice Region (SNP) | VAF 16/49 reads (33%) | catalogued as rs575797318, COSV101460040; called by muse, mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as rs745309220; called by mutect2, pindel, varscan2
- EHD3 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs200750745, COSV100434917; called by muse, mutect2, varscan2
- EIF3F | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.363); catalogued as rs1283067634, COSV100562671; called by muse, mutect2, varscan2
- EIF4A1 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99549303; called by muse, mutect2
- EIF4E1B | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100024950; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | catalogued as rs751148694; called by mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs770453803; called by mutect2, varscan2
- ENO2 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as rs959262748, COSV99145402; called by muse, mutect2, varscan2
- EP300 | c.6011A>G p.Q2004R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV99610121; called by muse, mutect2, varscan2
- EP300 | c.6499C>T p.Q2167* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99610124; called by muse, mutect2, varscan2
- EPB41L3 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1350949619, COSV59447862; called by muse, mutect2, varscan2
- EPHA6 | c.1942G>A p.A648T (on ENST00000389672 / NM_001080448.3; = p.A40T on NM_173655.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs770221629, COSV101066069; called by muse, mutect2, varscan2
- EPHB6 | c.165+1del | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | catalogued as rs771807343; called by mutect2, pindel, varscan2
- EPHX1 | c.1010T>C p.F337S | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV99689269; called by muse, mutect2
- ETV3L | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759795311, COSV101485630; called by muse, mutect2, varscan2
- EXOC7 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100135905; called by muse, mutect2, varscan2
- EXOSC9 | c.420T>G p.N140K | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99697201; called by muse, mutect2, varscan2
- EZH2 | c.1732C>T p.R578* (on ENST00000460911 / NM_001203247.2; = p.R583* on NM_004456.5) | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV57449148; called by muse, mutect2, varscan2
- FAAP24 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as COSV99579126; called by muse, mutect2, varscan2
- FAM111A | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as COSV100659502; called by muse, mutect2, varscan2
- FAM120C | c.1182G>C p.E394D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.358); catalogued as COSV100070557; called by muse, mutect2, varscan2
- FAM166A | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV100457747, COSV100458280; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM47B | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs143952389, COSV61453847, COSV61457134; called by muse, mutect2, varscan2
- FAM47C | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as rs782568130, COSV63724764; called by muse, mutect2, varscan2
- FAM81B | c.787-2A>G p.X263_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as rs1455196685, COSV99353311; called by muse, mutect2, varscan2
- FAM83C | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs193920940, COSV65584732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCE | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs375477547, COSV100003656; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs746983128; called by mutect2, varscan2
- FASN | c.6073G>A p.G2025R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100148448; called by muse, mutect2, varscan2
- FASN | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0.183); catalogued as rs759567154, COSV100148449, COSV60758883; called by muse, mutect2, varscan2
- FASTKD1 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.021); catalogued as rs769844413, COSV101494309; called by muse, mutect2, varscan2
- FAT1 | c.7231T>C p.C2411R | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.791); catalogued as COSV101499689; called by muse, mutect2, varscan2
- FAT2 | c.6560A>G p.Y2187C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99944419; called by muse, mutect2, varscan2
- FAT2 | c.2705G>A p.G902D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.503); catalogued as COSV99944420; called by muse, mutect2, varscan2
- FBN2 | c.6254dup p.G2086Wfs*6 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | catalogued as COSV52526735; called by mutect2, pindel, varscan2
- FBRS | c.41G>A p.R14Q (on ENST00000287468; = p.R534Q on NM_001105079.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs753786446, COSV99789435; called by muse, mutect2, varscan2
- FBXO16 | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100672517; called by muse, mutect2, varscan2
- FBXO5 | c.832A>G p.S278G | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344764799, COSV99999979; called by muse, mutect2, varscan2
- FBXO7 | c.1457G>A p.G486D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV99833022; called by muse, mutect2, varscan2
- FBXW10 | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs139724959; called by muse, mutect2
- FCGR2B | c.604T>C p.Y202H | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99375452; called by muse, mutect2
- FCGR2C | c.601T>C p.Y201H | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as COSV100913229; called by muse, varscan2
- FCRL1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1032164101, COSV100839923, COSV63825161; called by muse, mutect2, varscan2
- FCRL6 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs780674077, COSV58939935; called by muse, mutect2, varscan2
- FCRLA | c.926C>A p.P309H (on ENST00000367959; = p.P286H on NM_032738.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV99376755; called by mutect2, varscan2
- FER1L6 | c.1521T>C p.G507= | Splice Region (SNP) | VAF 15/45 reads (33%) | catalogued as COSV101206243; called by muse, mutect2, varscan2
- FERMT2 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV100449219; called by muse, mutect2, varscan2
- FGF13 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as COSV59549840; called by muse, mutect2, varscan2
- FGF3 | c.473A>T p.N158I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100490371; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 32/71 reads (45%) | catalogued as rs144178676; called by mutect2, varscan2
- FGFR4 | c.2056G>A p.G686R | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52812137, COSV99449737; called by muse, mutect2, varscan2
- FKBP9 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs747992780, COSV99639836; called by muse, mutect2, varscan2
- FLG | c.7283A>G p.H2428R | Missense Mutation (SNP) | VAF 63/363 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100912389; called by muse, mutect2, varscan2
- FLII | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374054347; called by muse, mutect2, varscan2
- FLNB | c.7402A>G p.K2468E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV99915441; called by muse, mutect2
- FLNC | c.6506C>T p.S2169F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV57956069; called by muse, mutect2, varscan2
- FLOT2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs373662636; called by muse, mutect2, varscan2
- FMN1 | c.4202C>A p.P1401H (on ENST00000616417 / NM_001277313.2; = p.P1178H on NM_001103184.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV100569418; called by muse, mutect2, varscan2
- FMN2 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs554313620, COSV60439450; called by muse, mutect2, varscan2
- FNDC3A | c.1943C>T p.A648V (on ENST00000492622 / NM_001079673.2; = p.A592V on NM_014923.5) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs1183680891, COSV68132428; called by muse, mutect2, varscan2
- FNIP2 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100033401; called by muse, mutect2, varscan2
- FOXM1 | c.2095G>A p.V699I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as rs369158837; called by muse, mutect2, varscan2
- FOXN4 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100142426; called by muse, mutect2, varscan2
- FOXR1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV100393080; called by muse, mutect2, varscan2
- FRMD4A | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs200078941, COSV99198382; called by muse, mutect2, varscan2
- FRMPD3 | c.1502C>A p.P501H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV99347318; called by muse, mutect2, varscan2
- FSTL5 | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100062276; called by muse, mutect2, varscan2
- FSTL5 | c.1599del p.V534Lfs*5 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as rs779560788, COSV60213555; called by mutect2, pindel, varscan2
- FTCD | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs371619712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs756304971; called by mutect2, varscan2
- FYTTD1 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV99612054; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GABBR1 | c.910T>C p.W304R | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100590181; called by muse, mutect2, varscan2
- GABRB2 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV99196901; called by muse, mutect2, varscan2
- GAK | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as rs532768885, COSV100034187, COSV58508480; called by muse, mutect2, varscan2
- GALNT5 | c.1970dup p.N657Kfs*4 | Frame Shift Ins (INS) | VAF 17/55 reads (31%) | catalogued as rs778901995; called by mutect2, pindel, varscan2
- GAS2L1 | c.1949C>A p.P650H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99329758; called by muse, mutect2, varscan2
- GASK1B | c.575del p.G192Afs*25 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | catalogued as rs1450763865, COSV56709157; called by mutect2, pindel, varscan2
- GBGT1 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs147110868; called by muse, mutect2, varscan2
- GBP4 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV100864492; called by muse, mutect2, varscan2
- GCM2 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV101069652; called by muse, mutect2, varscan2
- GCNA | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.094); catalogued as COSV65466167; called by muse, mutect2, varscan2
- GCNA | c.572A>G p.D191G | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as COSV101032756; called by muse, mutect2, varscan2
- GCNA | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs202033704, COSV101032758; called by muse, mutect2, varscan2
- GCOM1 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs748202049, COSV99985153; called by muse, mutect2, varscan2
- GFRA2 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as rs1418390951, COSV100152178; called by muse, mutect2, varscan2
- GLB1L2 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60277048; called by mutect2, varscan2
- GLDC | c.1839C>A p.F613L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100394713; called by muse, mutect2, varscan2
- GLMP | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99828187; called by muse, mutect2, varscan2
- GLP1R | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100952779; called by muse, mutect2
- GLRA2 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.44); catalogued as rs903978447, COSV54335394; called by muse, varscan2
- GNAS | c.1817A>G p.N606S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.264); catalogued as COSV100007985; called by muse, mutect2, varscan2
- GNAS | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV55690068; called by muse, mutect2, varscan2
- GOLGA4 | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100729224; called by muse, mutect2, varscan2
- GOLGA8A | c.277C>T p.H93Y (on ENST00000432566; = p.H65Y on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs1288008927, COSV100781659; called by mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs370114090; called by mutect2, varscan2
- GPAM | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV100788482; called by muse, mutect2, varscan2
- GPATCH8 | c.2344G>A p.G782S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100132933; called by muse, mutect2, varscan2
- GPBAR1 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV99946556; called by muse, mutect2, varscan2
- GPBP1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1043208499, COSV99303259; called by muse, mutect2, varscan2
- GPHN | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100018059; called by muse, mutect2, varscan2
- GPR142 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as COSV59520468; called by muse, mutect2, varscan2
- GPR153 | c.1007del p.P336Rfs*20 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as COSV64938744; called by mutect2, pindel, varscan2
- GPR173 | c.602A>G p.H201R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100212446; called by muse, mutect2, varscan2
- GPRIN3 | c.1237C>A p.L413I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.047); catalogued as COSV100311034; called by muse, mutect2, varscan2
- GPSM1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs371874960; called by muse, mutect2, varscan2
- GRAMD1A | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100526473; called by muse, mutect2, varscan2
- GRAMD1C | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs199937431; called by muse, mutect2, varscan2
- GRIA3 | c.791del p.G264Efs*25 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as COSV52060429; called by mutect2, varscan2
- GRIFIN | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs755226484, COSV101321781; called by muse, mutect2, varscan2
- GRIN2B | c.4265G>A p.R1422Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs75269586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRK6 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs769672004, COSV62683170; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 19/76 reads (25%) | catalogued as rs754199513; called by mutect2, varscan2*
- GSE1 | c.1491G>A p.W497* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99497338; called by muse, mutect2, varscan2
- GSK3A | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99725497; called by muse, mutect2
- GTF2IRD1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); catalogued as rs782300227, COSV99735786; called by muse, mutect2, varscan2
- GTF3C2 | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs754184411, COSV99273405; called by muse, mutect2, varscan2
- GYS2 | c.1823C>A p.A608D | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99680359; called by muse, mutect2, varscan2
- H3-5 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as COSV61188587; called by muse, mutect2, varscan2
- HAL | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1467184691, COSV99701708; called by muse, mutect2, varscan2
- HAUS4 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as rs764472995, COSV99247199; called by muse, mutect2, varscan2
- HAUS7 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100444389; called by muse, mutect2, varscan2
- HAUS8 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV53727173, COSV99505541; called by muse, mutect2, varscan2
- HCFC2 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99983363; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as COSV100625709; called by mutect2, varscan2
- HEATR5B | c.6146C>T p.A2049V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs567603070, COSV99250408; called by muse, mutect2, varscan2
- HERC2 | c.9281A>G p.E3094G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99877519; called by muse, mutect2, varscan2
- HHIPL1 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs762698095, COSV100415511; called by muse, mutect2, varscan2
- HID1 | c.2320G>A p.V774I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1235679948, COSV100173130; called by muse, mutect2, varscan2
- HIVEP1 | c.1796C>T p.T599I | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV101045879; called by muse, mutect2, varscan2
- HK1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs777012229, COSV100067948; called by muse, mutect2, varscan2
- HK2 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51873638, COSV51877065, COSV99309713; called by muse, mutect2, varscan2
- HK3 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs371743821, COSV99459609; called by mutect2, varscan2
- HLA-C | c.265_266del p.Q89Efs*9 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | catalogued as rs755090232; called by pindel, varscan2
- HMCN1 | c.5642G>A p.R1881Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.915); catalogued as rs768129329, COSV54890872; called by muse, mutect2, varscan2
- HMGCS1 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV100285109; called by muse, mutect2, varscan2
- HMGCS2 | c.829del p.I277Sfs*22 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs1557991740, COSV65568693; called by mutect2, pindel, varscan2
- HNRNPAB | c.265T>C p.Y89H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100359620, COSV57423056; called by muse, mutect2, varscan2
- HNRNPK | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100698891; called by muse, mutect2, varscan2
- HP | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs751924863, COSV100577682; called by muse, varscan2
- HP1BP3 | c.415del p.L139Ffs*6 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | catalogued as COSV100392016; called by mutect2, pindel, varscan2
- HPR | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs367988509, COSV57184029; called by muse, mutect2, varscan2
- HSCB | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs768337799, COSV99319728; called by muse, mutect2, varscan2
- HSD11B2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs755994842, COSV99341404; called by muse, mutect2, varscan2
- HSPA12A | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs558888605, COSV100980014; called by muse, mutect2, varscan2
- HSPG2 | c.9746G>A p.R3249H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs781212523, COSV101013581; called by muse, mutect2, varscan2
- HTR4 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.093); catalogued as COSV100090114; called by mutect2, varscan2
- HTT | c.3833T>C p.L1278P | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100751378; called by muse, mutect2, varscan2
- ICE2 | c.2690G>A p.G897D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.628); catalogued as rs779717082, COSV55031004; called by muse, mutect2, varscan2
- IDH2 | c.435dup p.T146Dfs*126 | Frame Shift Ins (INS) | VAF 13/35 reads (37%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, varscan2
- IFNE | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.805); catalogued as COSV100439107; called by muse, mutect2, varscan2
- IGDCC4 | c.2613dup p.T872Hfs*22 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | catalogued as rs761621429; called by mutect2, varscan2
- IGHG3 | c.1341G>T p.*447Yext*50 | Nonstop Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as rs749894637; called by muse, mutect2, varscan2
- IGKV1-39 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs780534208; called by mutect2, varscan2
- IGSF8 | c.479dup p.G161Rfs*18 | Frame Shift Ins (INS) | VAF 17/39 reads (44%) | catalogued as rs754902711; called by mutect2, varscan2
- IGSF9B | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100318633; called by muse, mutect2, varscan2
- IK | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs750508668, COSV70258386; called by muse, mutect2, varscan2
- IKBIP | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 34/69 reads (49%) | catalogued as rs759495433, COSV61081510; called by muse, mutect2, varscan2
- IKBKB | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs140546524, COSV60595829; called by muse, mutect2, varscan2
- IL18RAP | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs1388254813, COSV51824213; called by muse, mutect2, varscan2
- IL1R2 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs145651311, COSV100208321; called by muse, mutect2, varscan2
- IL1RL1 | c.824G>T p.S275I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99294638; called by muse, mutect2, varscan2
- IL20RA | c.807G>T p.M269I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100360166; called by muse, mutect2
- IL4R | c.2050del p.E684Kfs*3 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs1201023196; called by mutect2, pindel, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INAVA | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100950157; called by muse, mutect2
- INO80E | c.42del p.K14Nfs*5 | Frame Shift Del (DEL) | VAF 20/36 reads (56%) | catalogued as rs762875806; called by mutect2, varscan2
- INPP5F | c.631dup p.W211Lfs*3 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | catalogued as rs768918635; called by mutect2, varscan2
- INSRR | c.2851A>G p.T951A | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.297); catalogued as COSV100947284; called by muse, mutect2, varscan2
- INTS1 | c.3469G>A p.G1157R | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369996910, COSV67178091; called by muse, mutect2, varscan2
- INTS13 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as COSV99677695; called by muse, mutect2, varscan2
- INTS3 | c.1115G>T p.W372L | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100016639; called by muse, mutect2, varscan2
- INTS5 | c.1931T>C p.L644P | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100399874; called by muse, mutect2, varscan2
- INTS8 | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752848840, COSV57377601; called by muse, mutect2, varscan2
- IPO13 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.548); catalogued as rs1462508979, COSV100961306; called by muse, mutect2, varscan2
- IQSEC3 | c.1869G>T p.Q623H (on ENST00000538872 / NM_001170738.2; = p.Q320H on NM_015232.1) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100407803; called by muse, mutect2, varscan2
- IRF6 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.36); catalogued as COSV100884046; called by muse, mutect2, varscan2
- IRF9 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166537329, COSV100138223; called by muse, mutect2
- IRX2 | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV100121967; called by muse, mutect2, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs762230866, COSV99339624; called by mutect2, pindel, varscan2
- ITGA10 | c.2600G>A p.C867Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100995078; called by muse, mutect2, varscan2
- ITIH1 | c.2191G>A p.G731R | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs142551669; called by muse, mutect2, varscan2
- ITIH5 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144998429, COSV99906129; called by muse, mutect2, varscan2
- ITPR2 | c.3739C>T p.R1247* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1351836294, COSV101190266; called by muse, mutect2, varscan2
- ITPR3 | c.3155G>A p.G1052D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65407708; called by muse, mutect2, varscan2
- ITSN1 | c.561A>T p.R187S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.916); catalogued as rs1227209877, COSV101180643; called by muse, mutect2, varscan2
- JHY | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99913915; called by muse, mutect2, varscan2
- JKAMP | c.431C>T p.T144M (on ENST00000554271 / NM_001284201.1; = p.T130M on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99711796; called by muse, mutect2, varscan2
- JMJD6 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs374399276; called by muse, mutect2, varscan2
- KANK4 | c.340A>G p.N114D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100587774; called by muse, mutect2
- KAT14 | c.1751C>A p.A584D | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100890127; called by muse, mutect2, varscan2
- KAT2A | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV99863755; called by muse, mutect2, varscan2
- KAT2B | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV99770013; called by muse, mutect2, varscan2
- KBTBD7 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs780667713, COSV65266474; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNC3 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as COSV100979160; called by muse, mutect2, varscan2
- KCND1 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371441000, COSV99501957; called by muse, mutect2, varscan2
- KCNE5 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100927725; called by muse, mutect2, varscan2
- KCNH1 | c.2090T>C p.L697P (on ENST00000271751 / NM_172362.3; = p.L670P on NM_002238.4) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99661999; called by muse, mutect2, varscan2
- KCNIP3 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as rs747207327, COSV54671195; called by muse, mutect2, varscan2
- KCNJ11 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379245; called by muse, mutect2, varscan2
- KCNJ9 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.375); catalogued as COSV100081870; called by muse, mutect2, varscan2
- KCNS1 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV100067580; called by muse, mutect2, varscan2
- KCTD7 | c.710G>A p.R237Q (on ENST00000275532; = p.T250= on NM_153033.5) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs374256335; called by muse, mutect2, varscan2
- KDM3B | c.5049A>G p.I1683M | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100070350; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs142280183; called by mutect2, varscan2
- KDM6B | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1253485830, COSV54683988; called by muse, mutect2
- KDM6B | c.4357C>T p.R1453C | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99640855, COSV99642497; called by muse, mutect2, varscan2
- KHSRP | c.1109C>A p.A370D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101231261; called by muse, mutect2, varscan2
- KIAA0100 | c.3637C>A p.L1213M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV101197443; called by muse, mutect2, varscan2
- KIF21B | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs770974908, COSV59752730; called by muse, mutect2, varscan2
- KIF27 | c.4079G>A p.R1360Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761977367, COSV99927365; called by muse, mutect2, varscan2
- KLHL18 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775179182, COSV51744203; called by muse, mutect2, varscan2
- KLHL25 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100563767; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV52930337; called by mutect2, varscan2
- KLK2 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as rs1026540260, COSV100320083; called by mutect2, varscan2
- KRT20 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99391646; called by muse, mutect2, varscan2
- KRT5 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as rs539432563, COSV52863098; called by muse, mutect2, varscan2
- KRT71 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs771608163, COSV57291326; called by muse, mutect2, varscan2
- KRT76 | c.106T>A p.S36T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100196592; called by muse, mutect2, varscan2
- LAG3 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99180030; called by muse, mutect2, varscan2
- LAMA1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.87); catalogued as rs375547281; called by muse, mutect2, varscan2
- LAMA4 | c.4579G>T p.G1527C (on ENST00000230538 / NM_001105206.3; = p.G1520C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100039751; called by muse, mutect2, varscan2
- LAMC1 | c.4445C>T p.A1482V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); catalogued as COSV99280658; called by muse, mutect2, varscan2
- LARGE2 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs372844613; called by muse, mutect2, varscan2
- LARP4 | c.2054C>A p.P685H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99529781; called by muse, mutect2, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs746633076; called by mutect2, varscan2
- LATS2 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101231694; called by muse, mutect2, varscan2
- LCN12 | c.248C>G p.T83S | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV100861347; called by muse, mutect2, varscan2
- LCT | c.4369C>A p.L1457I | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as COSV99930668; called by muse, mutect2, varscan2
- LDHA | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV99908489; called by muse, mutect2, varscan2
- LDLRAP1 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746197297, COSV100974839; called by muse, mutect2, varscan2
- LGR6 | c.1012G>A p.A338T (on ENST00000367278 / NM_001017403.1; = p.A286T on NM_021636.3) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as rs767983891, COSV99708081; called by muse, mutect2, varscan2
- LIMCH1 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs551176123, COSV100574681; called by muse, varscan2
- LLGL1 | c.1892C>A p.P631H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as COSV100375140; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMBR1 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.756); catalogued as rs1314066185, COSV100626650; called by muse, mutect2, varscan2
- LMNA | c.1501G>T p.G501* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as COSV100738911; called by muse, mutect2
- LMNB1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99745824; called by muse, mutect2
- LONP1 | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as COSV100638801; called by muse, mutect2, varscan2
- LONRF2 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772883032, COSV101111076; called by muse, mutect2, varscan2
- LONRF2 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as rs1176119486, COSV66539664; called by muse, mutect2, varscan2
- LPA | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs778266525, COSV60300378; called by muse, mutect2, varscan2
- LPCAT3 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.595); catalogued as rs782409227, COSV54641143, COSV99780928; called by muse, mutect2, varscan2
- LPIN2 | c.1938C>T p.I646= | Splice Region (SNP) | VAF 21/50 reads (42%) | catalogued as rs766117626, COSV99859095; called by muse, mutect2, varscan2
- LRCH1 | c.225del p.L76* | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs1566138429; called by mutect2, pindel, varscan2
- LRGUK | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs544247071, COSV53638744; called by muse, mutect2, varscan2
- LRP1 | c.4907C>G p.T1636R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99677712; called by muse, mutect2, varscan2
- LRPAP1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs760183295, COSV56347272, COSV99579194; called by muse, mutect2, varscan2
- LRRC37B | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.524); catalogued as rs771239304, COSV100496589; called by muse, mutect2, varscan2
- LRRC3B | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.42); catalogued as COSV101186083; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRC45 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100141993; called by muse, mutect2
- LRRC49 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs763641412, COSV99538366; called by muse, mutect2, varscan2
- LRRK2 | c.1112G>A p.C371Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100111399; called by muse, mutect2
- LRRK2 | c.4654C>T p.R1552* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as rs921266719, COSV100111400; called by muse, mutect2, varscan2
- LRRN4 | c.1058T>G p.L353R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV101125547; called by muse, mutect2, varscan2
- LRRTM3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100791964; called by muse, mutect2, varscan2
- LRTOMT | c.44del p.P15Lfs*16 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as rs779229946; called by mutect2, pindel, varscan2
- LTF | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51605306; called by muse, mutect2, varscan2
- LYG2 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs372589731; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 26/42 reads (62%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEC3 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs1463756246, COSV100026262; called by muse, mutect2, varscan2
- MAGED1 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.995); catalogued as rs782215243, COSV100431905; called by muse, mutect2, varscan2
- MAGEH1 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100746851; called by muse, mutect2, varscan2
- MAGI1 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs149314563, COSV100442403; called by muse, mutect2, varscan2
- MALT1 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.27); catalogued as rs1265427907, COSV100618909; called by muse, mutect2, varscan2
- MARCHF6 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as COSV99930257; called by muse, mutect2, varscan2
- MAST3 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1207900722, COSV99446516; called by muse, mutect2, varscan2
- MBD6 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.947); catalogued as rs935307128, COSV100851860; called by muse, mutect2
- MCFD2 | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100109208; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs750092100; called by mutect2, varscan2
- MEAK7 | c.1080T>C p.G360= | Splice Region (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100640460; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MEIS1 | c.428A>T p.N143I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV99715914; called by muse, mutect2, varscan2
- MEOX2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as rs1205823681, COSV100012626; called by muse, mutect2, varscan2
- METTL8 | c.406A>G p.S136G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as rs1201886612, COSV100931150; called by muse, mutect2
- MGAM | c.3352A>G p.M1118V | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as rs763424236, COSV101527791; called by muse, mutect2, varscan2
- MGAT4C | c.1174del p.I392Lfs*3 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | catalogued as rs746398787; called by mutect2, varscan2
- MGMT | c.583G>A p.V195M (on ENST00000306010; = p.V164M on NM_002412.5) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.318); catalogued as rs373120552; called by muse, mutect2, varscan2
- MGRN1 | c.142del p.H48Tfs*13 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as COSV52148537; called by pindel, varscan2
- MIB1 | c.2026C>T p.R676* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as rs200545301; called by muse, mutect2, varscan2
- MIB1 | c.2780-1G>A p.X927_splice | Splice Site (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99839627; called by muse, mutect2, varscan2
- MIB2 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); catalogued as rs1463376829, COSV100599096; called by muse, mutect2
- MICAL1 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781228195, COSV100668798; called by muse, mutect2, varscan2
- MINDY3 | c.39G>T p.W13C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99510405; called by muse, mutect2, varscan2
- MISP | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145115054, COSV99297200; called by muse, mutect2, varscan2
- MKI67 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs764228841, COSV100897086; called by muse, mutect2, varscan2
- MKLN1 | c.2086+2T>C p.X696_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100760061; called by muse, mutect2, varscan2
- MLLT6 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774966274; called by muse, mutect2, varscan2
- MMP20 | c.129G>A p.A43= | Splice Region (SNP) | VAF 28/75 reads (37%) | catalogued as rs1353157655, COSV52778367; called by muse, mutect2, varscan2
- MMP24 | c.788C>A p.P263Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99864212; called by muse, mutect2, varscan2
- MNS1 | c.846_848del p.E282del | In Frame Del (DEL) | VAF 28/66 reads (42%) | catalogued as rs772432216; called by pindel, varscan2
- MOG | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs530507776, COSV100973179; called by muse, mutect2, varscan2
- MOV10 | c.837-1G>A p.X279_splice | Splice Site (SNP) | VAF 47/117 reads (40%) | catalogued as COSV100659810; called by muse, mutect2, varscan2
- MRAP | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV100353375; called by muse, mutect2, varscan2
- MRC2 | c.4065del p.P1357Rfs*8 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs1341032318, COSV100315977; called by mutect2, pindel, varscan2
- MROH2B | c.3453G>A p.M1151I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101270966; called by muse, mutect2, varscan2
- MROH6 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99435735; called by muse, mutect2, varscan2
- MRPL28 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs201250294, COSV51742809; called by muse, mutect2, varscan2
- MRPL38 | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99485633; called by muse, mutect2, varscan2
- MRPS9 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.971); catalogued as rs771129322, COSV99306444, COSV99306496; called by muse, mutect2, varscan2
- MSI2 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.599); catalogued as rs766409125, COSV99403760; called by muse, mutect2
- MSMP | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV100960414; called by muse, mutect2, varscan2
- MSS51 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs1236255589, COSV100200294; called by muse, mutect2, varscan2
- MST1R | c.2264del p.G755Vfs*19 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs1407832113; called by mutect2, pindel, varscan2
- MST1R | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99619948; called by muse, mutect2, varscan2
- MSTO1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99824445; called by muse, mutect2, varscan2
- MT1M | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99319356; called by muse, mutect2, varscan2
- MTFMT | c.541A>G p.R181G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99584581; called by muse, mutect2, varscan2
- MTSS1 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1252270636, COSV61496871; called by muse, mutect2, varscan2
- MTUS2 | c.3071G>A p.C1024Y | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.667); catalogued as COSV101462410; called by muse, mutect2
- MUC2 | c.2093G>A p.C698Y | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222862902; called by muse, mutect2, varscan2
- MUC2 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.24); catalogued as rs528181998; called by muse, mutect2, varscan2
- MUS81 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.599); catalogued as COSV100337435; called by mutect2, varscan2
- MVP | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62421711; called by muse, mutect2, varscan2
- MYBPC3 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as COSV99909317; called by muse, mutect2, varscan2
- MYH13 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs766166284, COSV99355877; called by muse, mutect2, varscan2
- MYH14 | c.3388C>A p.L1130M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as COSV99224467; called by muse, mutect2, varscan2
- MYH3 | c.4013G>A p.R1338H | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs761937084, COSV99878932; called by muse, mutect2, varscan2
- MYH4 | c.440del p.K147Sfs*21 | Frame Shift Del (DEL) | VAF 34/83 reads (41%) | catalogued as rs1465968113; called by mutect2, varscan2
- MYH6 | c.4158G>T p.E1386D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100676779; called by muse, mutect2, varscan2
- MYH7B | c.2005T>C p.Y669H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as rs759329721, COSV99483438; called by muse, varscan2
- MYL3 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs776163180, COSV52768394; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.3535G>A p.A1179T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV100659799; called by muse, mutect2, varscan2
- MYLK3 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs772851638, COSV101189249; called by muse, mutect2, varscan2
- MYO10 | c.5759C>A p.A1920D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV99946558; called by muse, mutect2, varscan2
- MYO10 | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1283903311, COSV99946561; called by muse, mutect2, varscan2
- MYO15A | c.10258T>A p.F3420I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as CD135884, COSV52766745; called by muse, mutect2
- MYO1A | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs139920718; called by muse, mutect2, varscan2
- MYO1D | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772579154, COSV100555075; called by muse, mutect2, varscan2
- MYO1G | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349222; called by muse, mutect2, varscan2
- MYO9B | c.3016G>A p.V1006M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs765214876, COSV68282208; called by muse, mutect2, varscan2
- MYO9B | c.4507C>T p.R1503C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761423620; called by muse, mutect2, varscan2
- MYOM1 | c.3562A>C p.S1188R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV99868811; called by muse, mutect2, varscan2
- NANOS2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.45); catalogued as rs377721853, COSV58024701; called by muse, mutect2, varscan2
- NAXE | c.779del p.G260Vfs*14 | Frame Shift Del (DEL) | VAF 25/157 reads (16%) | catalogued as rs778400879; called by mutect2, pindel, varscan2
- NBAS | c.5094G>T p.W1698C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99872068; called by muse, mutect2, varscan2
- NBPF1 | c.2356T>C p.S786P | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.731); catalogued as COSV99845063; called by muse, mutect2, varscan2
- NCAPD2 | c.1913T>C p.I638T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs755462892, COSV100217513; called by muse, mutect2, varscan2
- NCF4 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs1315752767, COSV99957601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCKAP5L | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs753791321, COSV100259338; called by muse, mutect2, varscan2
- NCKIPSD | c.1494C>A p.H498Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as COSV99584362; called by muse, mutect2, varscan2
- NCLN | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99860166; called by muse, mutect2, varscan2
- NCOA6 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs751634059, COSV100750443; called by muse, mutect2, varscan2
- NCOR2 | c.4559dup p.S1521Lfs*12 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | catalogued as rs1277381858; called by mutect2, pindel
- NCOR2 | c.2956del p.R986Gfs*77 | Frame Shift Del (DEL) | VAF 27/58 reads (47%) | catalogued as rs746871841; called by mutect2, pindel, varscan2
- NDNF | c.1407G>A p.W469* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV101113265; called by muse, mutect2, varscan2
- NEB | c.19691C>A p.S6564* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV51434252, COSV99428909; called by muse, mutect2, varscan2
- NEIL1 | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100748612; called by muse, mutect2, varscan2
- NELFB | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58025480; called by muse, mutect2, varscan2
- NFKB2 | c.2444G>A p.G815D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.803); catalogued as COSV99194244; called by muse, mutect2, varscan2
- NFX1 | c.1429T>C p.C477R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100582541; called by muse, mutect2, varscan2
- NFX1 | c.1715G>A p.C572Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100582543; called by muse, mutect2, varscan2
- NHS | c.4754C>T p.A1585V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV101197080; called by muse, mutect2, varscan2
- NHSL2 | c.1667C>T p.T556M (on ENST00000510661; = p.T922M on NM_001013627.2) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs752726540, COSV65453957; called by muse, mutect2, varscan2
- NID1 | c.1294del p.Q432Sfs*7 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | catalogued as COSV51631057; called by mutect2, pindel, varscan2
- NKTR | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs536150678, COSV51769497; called by muse, mutect2, varscan2
- NKX6-2 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100888366; called by muse, mutect2, varscan2
- NLRC5 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs1268721022, COSV99348472; called by muse, mutect2, varscan2
- NLRP3 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60230385; called by muse, mutect2, varscan2
- NME4 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV99556854; called by muse, mutect2, varscan2
- NMUR2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.255); catalogued as COSV99677416; called by muse, mutect2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | catalogued as rs754069719; called by mutect2, pindel, varscan2
- NOP14 | c.1631A>G p.D544G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100055135; called by muse, mutect2, varscan2
- NOP14 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100055137; called by muse, mutect2, varscan2
- NOTCH1 | c.195C>A p.S65R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as COSV53087332; called by muse, mutect2, varscan2
- NPHS1 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100800349; called by muse, mutect2, varscan2
- NPR1 | c.2483A>G p.E828G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100902092, COSV64118207; called by muse, varscan2
- NPRL3 | c.1307G>A p.G436D (on ENST00000611875 / NM_001077350.3; = p.G411D on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.638); catalogued as COSV99550115; called by muse, mutect2, varscan2
- NQO2 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100583280; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs774343392; called by mutect2, varscan2
- NR4A3 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100432836, COSV58243284; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs776154715; called by mutect2, varscan2
- NRP2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.992); catalogued as rs752149340, COSV55934787; called by muse, mutect2, varscan2
- NRXN2 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs950858043, COSV55460094; called by muse, mutect2, varscan2
- NTM | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs759790304, COSV100869294, COSV100869849; called by muse, mutect2, varscan2
- NUCB1 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99618195; called by muse, mutect2, varscan2
- NUMA1 | c.4558C>A p.L1520M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61188431; called by muse, mutect2, varscan2
- NUP153 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV100020990; called by muse, mutect2, varscan2
- NUP210L | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.44); catalogued as COSV99669336; called by muse, mutect2, varscan2
- NUP210L | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99666753; called by muse, mutect2, varscan2
- NUP62 | c.19G>T p.G7* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100352435; called by muse, mutect2, varscan2
- NXPH4 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100197493; called by muse, mutect2, varscan2
- NYAP2 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.176); catalogued as COSV99798918; called by mutect2, varscan2
- NYNRIN | c.2435_2437del p.F812del | In Frame Del (DEL) | VAF 18/47 reads (38%) | catalogued as rs780897384; called by pindel, varscan2
- NYNRIN | c.4213C>T p.L1405F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101230729; called by muse, mutect2, varscan2
- OAS3 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs201050892; called by muse, mutect2, varscan2
- OAZ1 | c.281del p.L94Yfs*8 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as COSV100457295; called by mutect2, pindel, varscan2
- OBSCN | c.7211T>C p.I2404T | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.911); catalogued as COSV99485759; called by muse, mutect2, varscan2
- OLFM2 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.232); catalogued as COSV99322134; called by muse, mutect2, varscan2
- OLIG2 | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.113); catalogued as COSV100324365; called by muse, mutect2, varscan2
- OLR1 | c.83A>G p.Q28R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1175621412, COSV100376452; called by muse, mutect2, varscan2
- OPRL1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937030973, COSV100402136; called by muse, mutect2, varscan2
- OR10AG1 | c.411A>G p.I137M | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100400246; called by muse, mutect2, varscan2
- OR10S1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV101602514; called by muse, mutect2
- OR1E2 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV99943528; called by muse, mutect2, varscan2
- OR2AK2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs143782385, COSV100823416; called by muse, mutect2, varscan2
- OR2Z1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV60691992; called by muse, mutect2, varscan2
- OR5D14 | c.220del p.C74Vfs*15 | Frame Shift Del (DEL) | VAF 37/138 reads (27%) | catalogued as COSV59456047; called by mutect2, pindel, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs746200712; called by mutect2, varscan2
- ORC4 | c.356A>T p.N119I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV99932545; called by muse, mutect2, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | catalogued as rs751106039; called by mutect2, varscan2
- OSBPL7 | c.826C>A p.L276M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99137197; called by muse, mutect2, varscan2
- OTUD7A | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV61043319; called by muse, mutect2, varscan2
- OVCH2 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV101491950; called by muse, mutect2, varscan2
- P3H3 | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368711010; called by muse, mutect2, varscan2
- PABPC4 | c.1693del p.Q565Rfs*33 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs769044699; called by mutect2, pindel, varscan2
- PACS1 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs552759820, COSV100270750; called by muse, mutect2, varscan2
- PAIP1 | c.1346+1G>A p.X449_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | catalogued as COSV59085430, COSV59086719; called by muse, mutect2, varscan2
- PAK3 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53272179; called by muse, mutect2, varscan2
- PALB2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200048921, COSV99849123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.753G>T p.E251D (on ENST00000259318 / NM_001136562.3; = p.E482D on NM_007203.5) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99395891; called by muse, mutect2
- PAMR1 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99553462; called by muse, mutect2
- PAN2 | c.2440C>T p.R814C (on ENST00000425394 / NM_001127460.3; = p.R810C on NM_014871.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs761017797, COSV57756400; called by muse, mutect2, varscan2
- PAN3 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); catalogued as rs768696158, COSV101111218; called by muse, mutect2
- PAPPA2 | c.1229del p.G410Efs*47 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | catalogued as COSV62772783; called by mutect2, pindel, varscan2
- PARP4 | c.3995G>A p.R1332H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs377036712; called by muse, mutect2
- PAX5 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs1323551948, COSV100814199, COSV100814676; called by muse, mutect2, varscan2
- PAXIP1 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101250163; called by muse, mutect2
- PCDH1 | c.3632T>C p.I1211T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV99747168; called by muse, mutect2, varscan2
- PCDH12 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.232); catalogued as rs866784886, COSV51523790, COSV99191741; called by muse, mutect2, varscan2
- PCDH19 | c.3046G>A p.A1016T (on ENST00000373034 / NM_001184880.2; = p.A968T on NM_020766.3) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV55257182; called by muse, mutect2, varscan2
- PCDHA1 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100974575; called by muse, mutect2
- PCDHA12 | c.1184T>C p.F395S | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100255726; called by muse, mutect2, varscan2
- PCDHB3 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV50564677, COSV50581609; called by muse, mutect2, varscan2
- PCDHB7 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as rs782319816, COSV99177570; called by muse, mutect2, varscan2
- PCDHGA2 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV53905469; called by muse, mutect2, varscan2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs772305388; called by mutect2, pindel, varscan2
- PCK2 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99394727; called by muse, mutect2, varscan2
- PCNT | c.4031C>T p.T1344I | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV100856165; called by muse, mutect2, varscan2
- PCNX1 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV99457629; called by muse, mutect2, varscan2
- PCSK6 | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100084216; called by muse, mutect2, varscan2
- PCYOX1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.505); catalogued as COSV100037354; called by muse, mutect2
- PDGFA | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100627402; called by muse, mutect2, varscan2
- PDGFRL | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs755681979, COSV99286740; called by muse, mutect2, varscan2
- PDIA4 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV99618971; called by muse, mutect2, varscan2
- PDLIM1 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1564595951, COSV100267640, COSV100267947; called by muse, mutect2, varscan2
1,095 further variants in this file (653 protein-altering or splice-affecting, 402 silent, 40 other) are not listed here.
